TARGET case TARGET-40-NAAHCF — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dc1f2aa9-86d0-5d63-a526-60891a84b089

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 16 years; Vital status: Dead; Days to death: 225 days.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.4; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 16.9 years (6,185 days); Year of diagnosis: 2002; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 225 days; Sites of involvement: Lung, NOS.
   Treatment given: Protocol identifier: BCM.

Follow-up (1 entry)
- Days to follow up: 225 days; Days to first event: 225 days; First event: Death; Year of follow up: 2003.

Biospecimens (2 samples)
- Sample TARGET-40-NAAHCF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHCF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 225
- Protocol: BCM
- Disease at diagnosis: Metastatic
- Metastasis site: Lung only
- Primary tumor site: Pelvis
- Specific tumor site: Acetabulum
- Histologic response: Stage 1/2 (0-90 % necrosis)
